Somatic mutation profile of tumor specimen 0DCM1G from CCDI case PBBLWW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.4 years (4,180 days).
Specimen 0DCM1G: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dd848fea-5436-456e-9e5b-121760747b26.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DCM19 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1d02bb8b-126e-45f2-933a-0132d22e1023

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 2, 3'UTR 1, Nonstop Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ZNF565 | c.662A>G p.H221R (on ENST00000355114; = p.H181R on NM_152477.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 318/832 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.181); catalogued as rs778213730; called by muse, mutect2, varscan2
- ZNF791 | c.1019G>A p.R340H | Missense Mutation (SNP) | VAF 50/539 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs143839457; called by muse, mutect2
- FNBP4 | c.1572G>T p.Q524H | Missense Mutation (SNP) | VAF 109/320 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- GDF10 | c.1435T>C p.*479Rext*69 | Nonstop Mutation (SNP) | VAF 30/709 reads (4%) | called by muse, mutect2
- U2SURP | c.3053A>G p.H1018R | Missense Mutation (SNP) | VAF 33/947 reads (3%) | SIFT tolerated (0.26); PolyPhen benign (0.017); called by muse, mutect2
- BECN2 | c.72G>A p.R24= | Silent (SNP) | VAF 62/628 reads (10%) | called by muse, mutect2
- RYR2 | c.6336C>T p.S2112= | Silent (SNP) | VAF 62/564 reads (11%) | catalogued as rs373777614; ClinVar: likely benign; called by muse, mutect2, varscan2
- GPR22 | c.*29A>T | 3'UTR (SNP) | VAF 36/624 reads (6%) | catalogued as rs369937943; called by muse, mutect2
- GPX4 | c.85-425C>A | Intron (SNP) | VAF 34/828 reads (4%) | called by muse, mutect2
